Somatic mutation profile of tumor specimen 0DPHTQ from CCDI case PBCDXB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.4 years (6,004 days).
Specimen 0DPHTQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d05a6cb9-75eb-41ba-b427-a90549a35bef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPHT1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73404313-65f5-43f3-b4ff-10dbc599584c

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAT3 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 145/374 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV60191797; called by muse, mutect2, varscan2
- CLMP | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 170/738 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV71650487; called by muse, mutect2
- COL4A5 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 171/207 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1052281498, COSV60366888; called by muse, mutect2, varscan2
- NAV1 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 167/392 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs759284972; called by muse, mutect2, varscan2
- OR1S1 | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 273/1003 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100515257; called by muse, mutect2, varscan2
- DNAH11 | c.2741T>C p.I914T | Missense Mutation (SNP) | VAF 250/586 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- HAUS2 | c.21G>C p.W7C | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 184/456 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA7 | c.2610C>T p.H870= | Silent (SNP) | VAF 119/347 reads (34%) | catalogued as rs1487343598, COSV54031537; called by muse, mutect2, varscan2
- AL031777.2 | c.153T>C p.Y51= | Silent (SNP) | VAF 202/449 reads (45%) | called by muse, mutect2, varscan2
- CLMP | c.738G>A p.L246= | Silent (SNP) | VAF 163/706 reads (23%) | called by muse, mutect2
- AC055839.2 | chr17:5501741 G>A | 5'Flank (SNP) | VAF 101/200 reads (51%) | catalogued as rs201316989; called by muse, mutect2, varscan2
